CCDI case PBBRUR — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Ovary.
https://portal.gdc.cancer.gov/cases/4e444682-e1a4-497c-b9dd-04e72bd06800

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Sertoli-Leydig cell tumor, poorly differentiated: ICD-O-3 morphology code: 8631/3; Tissue or organ of origin: Ovary; Age at diagnosis: 14.1 years (5,155 days).

Biospecimens (2 samples)
- Sample 0DH6ZZ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DH733: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
